CCDI case PBBUZR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/96c84401-42f3-465b-b82f-8522ba1e42f2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary microcarcinoma: ICD-O-3 morphology code: 8341/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.4 years (5,256 days).

Biospecimens (3 samples)
- Sample 0DIW62: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW6Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW7Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
